Gene-level copy-number profile of tumor specimen TCGA-A6-6781-01B from TCGA case TCGA-A6-6781, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 43.4 years (15,842 days).
Specimen TCGA-A6-6781-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.a86be412-93b1-4891-9eae-b2efe14f659b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-6781-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/e5fad84a-ad37-42a0-bfce-7861473ce248

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 35; copy number 2: 59,523; copy number 3: 3; copy number 4: 708; copy number 5: 1; copy number 7: 3; copy number 17: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-6781-01A-22D-A274-01): tumor purity 0.5, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:27,679,971–27,680,555, 1 gene, copy number 17: AL009179.2.
- chr10:4,201,141–4,243,912, 1 gene, copy number 5 (within-gene range 2–5): LINC00702.
- chr13:28,067,587–28,068,334, 1 gene, copy number 7: KATNBL1P1.
- chr20:1,561,385–1,620,061, 2 genes, copy number 7 (within-gene range 2–7): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
